Somatic mutation profile of tumor specimen 0DPDI2 from CCDI case PBCDLI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,024 days).
Specimen 0DPDI2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae84ccb9-7a41-4192-bbfc-b85a3c4cb36a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPDHD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46d959e9-7567-4a92-b968-995496b470b1

The open-access MAF lists 35 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, Nonsense Mutation 3, Intron 3, Splice Region 3, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3883-6G>A | Splice Region (SNP) | VAF 304/807 reads (38%) | catalogued as rs72664214, CS053443; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCNY | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 30/969 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.574); catalogued as rs914997774, COSV99591253; called by muse, mutect2
- HHIPL2 | c.2080G>A p.V694I | Missense Mutation (SNP) | VAF 460/841 reads (55%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.01); catalogued as rs375102365; called by muse, mutect2, varscan2
- PDIA4 | c.1328C>T p.A443V (on ENST00000286091 / NM_001371244.1; = p.A442V on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/499 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs376957387; called by muse, mutect2, varscan2
- PPARGC1B | c.2817-4G>A | Splice Region (SNP) | VAF 42/821 reads (5%) | catalogued as rs187554243; called by muse, mutect2
- PRSS27 | c.237-5G>A | Splice Region (SNP) | VAF 77/196 reads (39%) | catalogued as rs769891590; called by muse, mutect2, varscan2
- RSRC1 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 78/1466 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.687); catalogued as rs773664146, COSV99906157; called by muse, mutect2
- SYDE2 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 438/932 reads (47%) | catalogued as rs1459355157; called by mutect2, varscan2
- ZNF608 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 68/1464 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs112397217; called by muse, mutect2
- ADGRG2 | c.820C>T p.P274S (on ENST00000379869 / NM_001079858.3; = p.P271S on NM_005756.4) | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- AFF4 | c.2023C>A p.P675T | Missense Mutation (SNP) | VAF 100/602 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ANK1 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATL2 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 104/2294 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2
- ATP4A | c.3077G>A p.G1026E | Missense Mutation (SNP) | VAF 77/559 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- B3GALT2 | c.967C>A p.L323M | Missense Mutation (SNP) | VAF 36/848 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.393); called by muse, mutect2
- CXCL8 | c.47C>A p.S16Y | Missense Mutation (SNP) | VAF 66/1556 reads (4%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.879); called by muse, mutect2
- FAM47C | c.910C>A p.P304T | Missense Mutation (SNP) | VAF 61/470 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- GUCY1A2 | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 66/1548 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); called by muse, mutect2
- LARP1 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 111/684 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- SEC11A | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 144/1011 reads (14%) | called by muse, mutect2, varscan2
- TXK | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 325/752 reads (43%) | called by muse, mutect2, varscan2
- USP29 | c.1655G>T p.S552I | Missense Mutation (SNP) | VAF 175/713 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ABLIM1 | c.2037G>A p.G679= | Silent (SNP) | VAF 30/860 reads (3%) | called by muse, mutect2
- COX6A2 | c.165G>A p.P55= | Silent (SNP) | VAF 29/638 reads (5%) | catalogued as COSV54932028; called by muse, mutect2
- DOCK6 | c.5391C>T p.D1797= | Silent (SNP) | VAF 262/600 reads (44%) | catalogued as rs762281671; called by muse, mutect2, varscan2
- FSCN2 | c.222C>T p.D74= | Silent (SNP) | VAF 531/807 reads (66%) | catalogued as rs531941328; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP12 | c.1956C>T p.F652= | Silent (SNP) | VAF 270/1050 reads (26%) | called by muse, mutect2, varscan2
- PPFIA4 | c.765C>T p.T255= | Silent (SNP) | VAF 82/944 reads (9%) | catalogued as rs773764303, COSV55320591; called by muse, mutect2
- SERPINB3 | c.753C>A p.I251= | Silent (SNP) | VAF 175/1057 reads (17%) | catalogued as rs143869105, COSV52189658; called by muse, mutect2, varscan2
- TBRG4 | c.1002C>T p.H334= | Silent (SNP) | VAF 475/1022 reads (46%) | called by muse, mutect2, varscan2
- CCDC149 | c.63+17775G>A | Intron (SNP) | VAF 200/1135 reads (18%) | catalogued as rs970712918; called by muse, mutect2, varscan2
- IGHMBP2 | c.711+27C>A | Intron (SNP) | VAF 72/379 reads (19%) | called by muse, mutect2, varscan2
- KCNIP4 | c.61+251046C>T | Intron (SNP) | VAF 8/84 reads (10%) | catalogued as rs1028218157; called by muse, mutect2
- LASP1 | c.-97C>T | 5'UTR (SNP) | VAF 10/58 reads (17%) | catalogued as rs1249303600; called by muse, varscan2
- SPEG | c.-90C>A | 5'UTR (SNP) | VAF 16/78 reads (21%) | called by mutect2, varscan2
